Somatic mutation profile of tumor specimen TCGA-A4-8311-01A (aliquot TCGA-A4-8311-01A-11D-2396-08) from TCGA case TCGA-A4-8311, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.8 years (22,220 days).
Specimen TCGA-A4-8311-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ec262e6-d87e-4042-b00c-ccb065e9b804.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-8311-10A (Blood Derived Normal), aliquot TCGA-A4-8311-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f06edfc-0834-4efb-bc0f-c5de231ab205

The open-access MAF lists 55 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 29, Silent 17, Frame Shift Del 6, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD28 | c.1264A>G p.N422D | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV67520587; called by muse, mutect2, varscan2
- ARHGEF12 | c.4396G>T p.A1466S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as COSV63105024, COSV63108073; called by muse, mutect2, varscan2
- CATSPER1 | c.1691+1G>A p.X564_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV56414198; called by muse, mutect2, varscan2
- DDX27 | c.36A>C p.E12D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV65631193; called by muse, mutect2, varscan2
- EVI2A | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 107/182 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV55986048, COSV55987276; called by muse, mutect2, varscan2
- IL9 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV50853769; called by muse, mutect2, varscan2
- KRT26 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 61/199 reads (31%) | catalogued as COSV59416295; called by muse, mutect2, varscan2
- LARP4 | c.1016T>C p.L339P | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53327935; called by muse, mutect2, varscan2
- LMTK3 | c.3566C>T p.T1189M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV54318345; called by muse, mutect2
- MAPK6 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55932153; called by muse, mutect2, varscan2
- MEP1B | c.889A>T p.S297C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1368693447, COSV52500648; called by muse, varscan2
- MFSD10 | c.605T>C p.M202T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53275682; called by muse, mutect2, varscan2
- MUC5B | c.15429G>C p.M5143I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV71596685; called by muse, mutect2, varscan2
- PCDH17 | c.1675del p.A559Rfs*11 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | catalogued as COSV64977233; called by mutect2, pindel, varscan2
- PEX14 | c.384+1G>A p.X128_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV63064080; called by muse, mutect2, varscan2
- PXYLP1 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53894007; called by muse, mutect2, varscan2
- RALGAPB | c.1706C>A p.P569H | Missense Mutation (SNP) | VAF 141/227 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV53443174; called by muse, mutect2, varscan2
- SACM1L | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV66615566; called by muse, mutect2, varscan2
- SCLY | c.629T>C p.I210T (on ENST00000651534; = p.I202T on NM_016510.7) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs548740545, COSV54545165; called by muse, mutect2
- SEC14L3 | c.102T>A p.D34E | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV53181082; called by muse, mutect2, varscan2
- SH3BP2 | c.142del p.L48Cfs*28 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV62554501; called by pindel, varscan2*
- SLC66A2 | c.530T>A p.L177Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60845721; called by muse, mutect2, varscan2
- SULF2 | c.2342A>T p.Y781F | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV63420777; called by muse, mutect2, varscan2
- TAF2 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65422126; called by muse, mutect2, varscan2
- THOC2 | c.3653A>T p.K1218I | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV55557688; called by muse, mutect2, varscan2
- TMEM250 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs760793959, COSV69308238; called by muse, mutect2
- TMEM72 | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV67461418; called by muse, mutect2, varscan2
- TNFSF15 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65011070; called by muse, mutect2, varscan2
- TUT4 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57120863; called by muse, mutect2, varscan2
- UGT1A3 | c.557A>G p.Q186R | Missense Mutation (SNP) | VAF 113/232 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.601); catalogued as rs997425766, COSV100530466; called by muse, mutect2, varscan2
- ULK2 | c.26A>T p.Y9F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV64449200; called by muse, mutect2, varscan2
- UQCR10 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as rs1416449924, COSV57459142; called by muse, mutect2, varscan2
- VCPIP1 | c.2081T>C p.L694P | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60050522; called by muse, mutect2, varscan2
- ZNF514 | c.1093T>G p.F365V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV54635712; called by muse, mutect2, varscan2
- KIDINS220 | c.4093del p.S1365Pfs*33 | Frame Shift Del (DEL) | VAF 39/129 reads (30%) | called by mutect2, pindel, varscan2
- MTHFD1 | c.2223_2224del p.Q741Hfs*2 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- PDZD8 | c.1144_1148delinsG p.R382Vfs*40 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by pindel, varscan2*
- ZNF263 | c.1468del p.Y490Tfs*66 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- BCL9L | c.2469G>A p.Q823= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV52690214; called by muse, mutect2, varscan2
- CLTRN | c.39T>C p.H13= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV66712567; called by muse, mutect2, varscan2
- GALNT2 | c.534C>T p.S178= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV64198162; called by muse, mutect2, varscan2
- HNF1B | c.393A>G p.Q131= | Silent (SNP) | VAF 41/64 reads (64%) | called by muse, mutect2, varscan2
- MUC16 | c.9660C>A p.I3220= | Silent (SNP) | VAF 64/144 reads (44%) | catalogued as COSV67497129, COSV67502592; called by muse, mutect2, varscan2
- NARF | c.1113C>T p.V371= | Silent (SNP) | VAF 82/114 reads (72%) | catalogued as COSV59114114; called by muse, mutect2, varscan2
- PRKDC | c.8217C>A p.L2739= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as COSV58067191; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1686G>A p.T562= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as rs935132125, COSV51938800; called by muse, mutect2, varscan2
- SLC35A4 | c.525T>A p.A175= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV60054835; called by muse, mutect2, varscan2
- SLCO6A1 | c.345G>T p.L115= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV65815889; called by muse, mutect2, varscan2
- SNTA1 | c.372C>T p.D124= | Silent (SNP) | VAF 71/228 reads (31%) | catalogued as COSV54131313; called by muse, mutect2, varscan2
- SRBD1 | c.2772C>G p.G924= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV55407023; called by muse, mutect2, varscan2
- SUN2 | c.922C>T p.L308= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs1228386473, COSV53302472; called by muse, mutect2, varscan2
- TAMALIN | c.213C>A p.L71= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV53337716, COSV53337951; called by muse, varscan2
- TREM2 | c.378G>A p.V126= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58296041; called by muse, mutect2, varscan2
- WDR91 | c.1818G>A p.E606= | Silent (SNP) | VAF 61/287 reads (21%) | catalogued as COSV60372417; called by muse, mutect2, varscan2
- ZNF721 | c.1164T>C p.S388= (on ENST00000338977; = p.S400= on NM_133474.4) | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs1553863598, COSV59097968; called by muse, mutect2, varscan2
